Surgical pathology report (de-identified scan), TCGA case TCGA-XF-AAMJ, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-AAMJ-01A (Primary Tumor).

[page 1 of 6]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

ICD-O-3
Carcinoma, urothelial NOS
8120/3
Site: Bladder NOS
C67.9
J 3/26/14

Document Type:

*Date - Date of Service:

Document Status:

Document Title:

Encounter info:

Contributor System:

* Final Report *

ORDERING PHYSICIAN:

Ordering Physician:

PRE-OPERATIVE DIAGNOSIS:

Bladder Cancer, H/O Prostate Cancer

MICROSCOPIC DESCRIPTION:

A-C: See final microscopic-diagnosis.

D: Sections of the bladder show extensive sheets of cells with high N/C ratio and prominent nuclei with nucleoli forming papillary structures and extensively invading into muscularis propria involving the entire thickness of the bladder wall (D5-8,11). The tumor extends into the perivesical fat and up to the posterior inked bladder wall margin (D6). The adjacent mucosa shows multifocal areas of urothelial carcinoma in situ (D7). Multiple sections of the bladder mucosa show cystitis cystica and cystitis glandularis (D7,9,13,16,17). A section from the urethra shows residual periurethral prostatic tissue (D18). A section of benign seminal vesicle is also identified (D20). The tumor involves the entire posterior wall and extends laterally (predominantly left lateral) into the trigone and anterior mucosal wall. A section of left ureter (D4) shows complete obstruction of the ureter with tumor. The tumor also involves the right ureterovesical junction (D1). Multiple lymph nodes sampled show no evidence of metastatic disease.

E-N: See final microscopic-diagnosis.

Signature Line

Signed by:

ELECTRONIC SIGNATURE

GROSS DESCRIPTION:

A: The specimen is received fresh from the O.R. and labeled "Right distal ureter". It consists of a segment of ureter measuring 1 x 1 x 0.4 cm. The specimen is entirely submitted for frozen section.

Printed by:

Printed on:

Page 1 of 6
(Continued)

[page 2 of 6]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

B: The specimen is received fresh from the O.R. and labeled "Left distal ureter". It consists of a segment of ureter measuring 0.9 x 0.8 x 0.4 cm. The specimen is entirely submitted for frozen section.

C: The specimen is received fresh from the O.R. and labeled "Urethral margin". It consists of a strip of mucosa and submucosal tissue measuring 1.7 x 0.5 x 0.5 cm. The specimen is entirely submitted for frozen section.

D: The specimen is received fresh from the O.R. and labeled "Bladder / prostate". It consists of a cystectomy measuring overall 15 x 9 x 7.5 cm. The peritoneum measures 9 x 8.5 x less than 0.2 cm and appears uninvolved. The bladder itself measures 9 x 8 x 6 cm and the anterior and posterior surface are firm and nodular to palpation, and the left lateral end of bladder and resection of specimen is a nodule probably representing tumor. The bladder is opened anteriorly in a "Y" shaped incision to reveal a large ulcerated mass occupying the entire posterior bladder wall and extending onto the lateral wall, measuring 5 x 5 x 2 cm. The tumor involves the right ureterovesical junction and the left ureterovesical junction is completely obscured by the tumor. The surrounding mucosa is edematous, hemorrhagic and slightly trabeculated. The trigone is involved by tumor. The uninvolved wall thickness measures 0.8 cm. The involved wall measures 2 cm and the tumor invades through the entire thickness of the bladder and extends to the perivesicular fat, and abuts the inked surgical margin in the left lateral posterior aspect of the specimen. A prostate is not identified. Bilateral ureters are explored; the right distal ureter measures 6.5 cm in length and 1.1 cm in diameter. The left distal ureter is completely obstructed and disrupted by the tumor. Although a 3 cm segment of the left distal ureter is identified, the remaining of the left ureter is embedded within the tumor and is not grossly identifiable. The left ureter is dilated and measures 2.2 cm in circumference. Representative sections are entirely submitted in twenty cassettes.

E: The specimen is received fresh from the O.R. and labeled "True posterior vascular pedicle stitch @ true margin". It consists of a pink-tan soft tissue fragment with suture at one end and designated as true margin measuring 2.5 x 1 x 0.8 cm. The true margin is inked black. The specimen is serially sectioned and entirely submitted in two cassettes.

F: The specimen is received in formalin and labeled "Left para aortic lymph nodes". It consists of two pink-tan soft tissue fragments measuring in aggregate 2.5 x 2 x 1.5 cm. The specimen is entirely submitted in two cassettes.

G: The specimen is received in formalin and labeled "Right common iliac lymph nodes". It consists of adipose tissue fragments measuring in aggregate 3.5 x 2 x 1 cm. The specimen is entirely submitted in two cassettes.

H: The specimen is received in formalin and labeled "Left common iliac lymph nodes". It consists of adipose tissue fragments measuring in aggregate 3 x 2 x 1 cm. The specimen is entirely submitted in three cassettes.

I: The specimen is received in formalin and labeled "Right para cava lymph nodes". It consists of adipose tissue fragments measuring in aggregate 2.5 x 1.5 x 0.8 cm. The specimen is entirely submitted in two cassettes.

J: The specimen is received in formalin and labeled "Left external iliac lymph nodes". It consists of adipose tissue

Printed by:
Printed on:

Page 2 of 6
(Continued)

[page 3 of 6]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

fragments measuring in aggregate 2.5 x 2 x 1.5 cm. The specimen is entirely submitted in two cassettes.

K: The specimen is received in formalin and labeled "Left hypogastric / obturator lymph nodes". It consists of adipose tissue fragments measuring in aggregate 2 x 1.5 x 1 cm. The specimen is entirely submitted in one cassette.

L: The specimen is received in formalin and labeled "Left para obturator nerve". It consists of firm pink-tan soft tissue and a small fragment of what grossly appears to be nerve measuring in aggregate 1.5 cm in length and 0.4 cm in diameter, attached to larger fragments. Representative sections are entirely submitted in two cassettes.

M: The specimen is received in formalin and labeled "Left proximal ureter". It consists of a segment of ureter measuring 0.9 cm and 0.7 cm in diameter. The specimen is trisected and entirely submitted in one cassette.

N: The specimen is received in formalin and labeled "Right proximal ureter". It consists of a segment of ureter and two clips measuring 1.5 cm and an average diameter measuring 0.5 cm. The specimen is trisected and entirely submitted in one cassette.

SECTIONS:

AFS: frozen section, right distal ureter all embedded
BFS: frozen section, left distal ureter all embedded
CFS: frozen section, urethral margin all embedded
D1: right ureteral margin all embedded
D2: left ureteral margin all embedded
D3: right ureterovesical junction and ureter all embedded
D4: left ureter all embedded
D5-6: posterior bladder wall, full thickness all embedded
D7: posterior upper bladder wall all embedded
D8: left lateral posterior wall all embedded
D9: right lateral wall all embedded
D10: dome of bladder all embedded
D11: trigone all embedded
D12: anterior wall all embedded
D13: uninvolved wall all embedded
D14-15: additional lower posterior wall all embedded
D16-17: additional tumor all embedded
D18: urethra all embedded
D19: additional surrounding mucosa all embedded
D20: possible lymph nodes all embedded
E1,2: true posterior vascular pedicle stitch at true margin, serially sectioned all embedded
F1-2: left para aortic lymph nodes all embedded
G1: multiple nodes, one large node, bisected all embedded

Printed by:
Printed on:

Page 3 of 6
(Continued)

[page 4 of 6]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

G2: remaining tissue all embedded
H1-3: left common iliac lymph nodes all embedded
I1-2: right para cava lymph nodes all embedded
J1-2: left external iliac lymph nodes all embedded
K: left hypogastric / obturator lymph nodes all embedded
L1-2: left para obturator nerve all embedded
M: left proximal ureter, trisected all embedded
N: right proximal ureter, trisected all embedded

INTRAOPERATIVE DIAGNOSIS:

FROZEN SECTION DIAGNOSIS:

AFS: Right distal ureter
no tumor identified

BFS: Left distal ureter
no tumor identified

CFS: Urethral margin
no tumor identified

FINAL DIAGNOSIS:

RADICAL CYSTECTOMY, URINARY DIVERSION:

RIGHT DISTAL URETER (A):

FROZEN SECTION DIAGNOSIS:

- NO TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN UROTHELIUM
- NO DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT DISTAL URETER (B):

FROZEN SECTION DIAGNOSIS:

- NO TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN UROTHELIUM
- NO DYSPLASIA OR MALIGNANCY IDENTIFIED

Printed by:
Printed on:

Page 4 of 6
(Continued)

[page 5 of 6]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

URETHRAL MARGIN (C):

FROZEN SECTION DIAGNOSIS:

- NO TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN UROTHELIUM
- NO DYSPLASIA OR MALIGNANCY IDENTIFIED

BLADDER / PROSTATE (D):

BLADDER ONLY (NO PROSTATE RECEIVED):

- POORLY DIFFERENTIATED UROTHELIAL CARCINOMA, NUCLEAR GRADE 4/4, INVOLVING ENTIRE BLADDER WALL AND EXTENDING INTO SURROUNDING PERIVESICAL SOFT TISSUE
- MULTIFOCAL UROTHELIAL CARCINOMA IN SITU
- VASCULAR AND PERINEURAL INVASION IDENTIFIED
- TUMOR FOCALLY EXTENDS THROUGH INKED POSTERIOR MARGIN (5% OF THE MARGIN INVOLVE BY INVASIVE TUMOR)
- DISTAL URETERAL AND URETHRAL MARGINS, FREE OF MALIGNANCY
- MULTIFOCAL CYSTITIS GLANDULARIS AND CYSTITIS CYSTICA

TRUE POSTERIOR VASCULAR PEDICLE (E):

- BENIGN FIBROVASCULAR AND ADIPOSE TISSUE SHOWING FAT NECROSIS
- NO MALIGNANCY IDENTIFIED

LEFT PARAAORTIC LYMPH NODES (F):

- NO EVIDENCE OF METASTATIC DISEASE IN SEVEN LYMPH NODES EXAMINED (0/7)

RIGHT COMMON ILIAC LYMPH NODES (G):

- NO EVIDENCE OF METASTATIC DISEASE IN NINE LYMPH NODES EXAMINED (0/9)

LEFT COMMON ILIAC LYMPH NODES (H):

- NO EVIDENCE OF METASTATIC DISEASE IN EIGHT LYMPH NODES EXAMINED (0/8)

RIGHT PARACAVAL LYMPH NODES (I):

- NO EVIDENCE OF METASTATIC DISEASE IN TEN LYMPH NODES EXAMINED (0/10)

LEFT EXTERNAL ILIAC LYMPH NODES (J):

- NO EVIDENCE OF METASTATIC DISEASE IN FOUR LYMPH NODES EXAMINED (0/4)

LEFT HYPOGASTRIC / OBTURATOR LYMPH NODES (K):

Printed by:

Printed on:

Page 5 of 8
(Continued)

[page 6 of 6]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

- NO EVIDENCE OF METASTATIC DISEASE IN FOUR LYMPH NODES EXAMINED (0/4)

LEFT PARA OBTURATOR NERVE (L):

- NO EVIDENCE OF METASTATIC DISEASE IN ONE LYMPH NODE EXAMINED (0/1)
- BENIGN NERVE AND FIBROADIPOSE TISSUE SHOWING EXTENSIVE FAT NECROSIS
- NO MALIGNANCY IDENTIFIED

LEFT PROXIMAL URETER (M):

- BENIGN UROTHELIUM
- NO DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT PROXIMAL URETER (N):

- BENIGN UROTHELIUM
- NO DYSPLASIA OR MALIGNANCY IDENTIFIED

PATHOLOGIC TNM STAGE: pT3bN0MXR1

CLINICAL DIAGNOSIS:

Bladder cancer

Completed Action List:

Printed by:
Printed on:

Page 6 of 6
(End of Report)

Source: NCI Genomic Data Commons file 9bfb0df6-5385-4a83-bc7a-02bd3f0a694e (TCGA-XF-AAMJ.40212BF3-FE4C-4B89-8583-76C73560DD2C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).